Gene-level copy-number profile of tumor specimen TCGA-X6-A8C5-01A from TCGA case TCGA-X6-A8C5, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 63.9 years (23,350 days).
Specimen TCGA-X6-A8C5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.2a1af1a0-e321-4d5d-937b-013a4faef870.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-X6-A8C5-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/057c34ef-87e9-45aa-bf52-8c0c53b3835f

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 33; copy number 1: 80; copy number 2: 10,508; copy number 3: 2,488; copy number 4: 45,523; copy number 7: 1,186.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-X6-A8C5-01A-11D-A36I-01): tumor purity 0.77, ploidy 1.87, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 33 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:152,374,998–152,726,160, 1 gene (within-gene range 0–2): AC008571.2.
- chr5:152,495,718–154,494,743, 18 genes: AC008571.1, LINC01470, GRIA1, RN7SL177P, LINC01861, AC091962.1, FAM114A2, MFAP3, GALNT10, SAP30L-AS1, HNRNPA3P7, AC008625.1, MIR1294, RN7SL655P, SAP30L, HAND1, AC026688.2, AC026688.1.
- chr13:49,956,670–50,125,720, 1 gene (within-gene range 0–2): DLEU2.
- chr13:50,044,649–50,081,978, 8 genes: AL137060.9, AL137060.7, MIR16-1, MIR15A, AL137060.4, AL137060.2, AL137060.8, AL137060.5.
- chr13:50,082,295–50,173,181, 5 genes: AL137060.6, RPL18P10, AL137060.1, AL137060.3, ST13P4.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 80. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
